Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0VT, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0VT-01A (Primary Tumor).

adenocarcinoma, endometrioid, NOS 8380/3
Site: Endometrium C54.1 lw 5/1/11

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Endometrial cancer.

LMP DATE: Not applicable.

PROCEDURE: Laparoscopic abdominal hysterectomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy, omentectomy, bilateral pelvic and paraortic lymph node dissection, pelvic biopsies.

SPECIFIC CLINICAL QUESTION: Not provided.

OUTSIDE TISSUE DIAGNOSIS: No.

PRIOR MALIGNANCY: No.

CHEMORADIATION THERAPY: No.

OTHER DISEASES: No.

ADDENDA:

Addendum

Molecular testing on both endometrial and ovarian tumors identified loss of heterozygosity (LOH) in both tumors at chromosomes 1q and 14q. The interpretation was: two targets likely of the same clonal origin with moderate reliability. For details, please refer to molecular pathology report.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL CARCINOMA & CARCINOSARCOMA : HYSTERECTOMY

SPECIMENS

TUMOR TYPE: Endometrioid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Moderately differentiated (FIGO 2)

ARCHITECTURAL GRADE: Moderately differentiated

NUCLEAR GRADE: Grade 2

TUMOR SIZE: Maximum dimension: 114 mm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 95 %, Posterior endomyometrium: 85 %

DEPTH OF INVASION: Less than 1/2 thickness of myometrium

STRUCTURES INVOLVED: Endocervical glands, Cervical stroma

ANGIOLYMPHATIC INVASION: No

PRE-NEOPLASTIC CONDITIONS: Complex endometrial hyperplasia with atypia

OTHER: Adenomyosis

LYMPH NODES POSITIVE: Number of lymph nodes positive: 0

LYMPH NODES EXAMINED: Total number of lymph nodes examined: 6

T STAGE, PATHOLOGIC: pT2

N STAGE, PATHOLOGIC: pN0

M STAGE, PATHOLOGIC: Not applicable

FIGO STAGE: II

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION: Right

PROCEDURE: TAH with salpingo-oophorectomy

TUMOR SIZE: Maximum dimension (right ovary): 70 mm

TUMOR TYPE: Endometrioid carcinoma

HISTOLOGIC SILVERBERG GRADE: Moderately differentiated (6-7 pts)

ARCHITECTURAL PATTERN: Papillary (2)

CYTOLOGIC ATYPIA: Marked (3)

MITOTIC COUNTS / 10hpf: 0-9 (1)

VASCULAR INVASION: No

TUMOR CAPSULE: Ruptured

PERITONEAL TUMOR SIZE:

MALIGNANT CELLS IN ASCITES OR

PERITONEAL WASHING: Yes

LYMPH NODES EXAMINED: Total number of lymph nodes examined: 6

LYMPH NODES POSITIVE: Number of positive lymph nodes, Right: 0

Number of positive lymph nodes, Left: 0

pT2c

pN0

Not applicable

FIGO STAGE: IIC

Source: NCI Genomic Data Commons file 9637bc0b-40cd-4f0f-96e7-e9dd9d92bde1 (TCGA-BG-A0VT.0BC38740-A7B9-4086-9F03-A139287B33CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).